Somatic mutation profile of tumor specimen C3N-03457-02 (aliquot CPT0246620006) from CPTAC case C3N-03457, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 71.3 years (26,052 days).
Specimen C3N-03457-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 967aa381-5f22-44c8-8e16-3cb430718aef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03457-31 (Blood Derived Normal), aliquot CPT0246660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc1de6f-d97b-4450-884d-7b3df4e620e0

The open-access MAF lists 290 somatic variants for this specimen: 196 protein-altering or splice-affecting, 63 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 63, Intron 18, Nonsense Mutation 16, 5'UTR 4, RNA 4, 3'UTR 3, Frame Shift Del 2, Splice Site 2, 3'Flank 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 54/651 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- PSEN2 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750666, CM023438; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 52/417 reads (12%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN2 | c.2058C>G p.I686M | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.153); catalogued as COSV63974329; called by muse, mutect2
- AJAP1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.84); catalogued as COSV65451301; called by muse, mutect2
- ALKBH5 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV52756512; called by muse, mutect2
- AMPH | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs960856901, COSV100341316; called by muse, mutect2, varscan2
- ARHGEF10 | c.2110C>T p.H704Y (on ENST00000398564; = p.H679Y on NM_014629.4) | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV50649531; called by muse, mutect2
- ARPC2 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV55283588; called by muse, mutect2
- ASXL1 | c.2314G>C p.A772P | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1261856158, COSV60114358; called by muse, mutect2
- BARX2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs772560593, COSV99858719; called by muse, mutect2, varscan2
- C22orf23 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV50777834; called by muse, mutect2
- CACNG8 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs1438290561, COSV99555069; called by muse, mutect2
- CDH10 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 17/160 reads (11%) | catalogued as COSV100051624; called by mutect2, varscan2
- CDH6 | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54070992; called by muse, mutect2
- CDHR1 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186550945, COSV100259232; called by muse, mutect2
- CDIPT | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as COSV99570101; called by muse, mutect2, varscan2
- CDK17 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as COSV54127395; called by muse, mutect2
- CFAP44 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1297846337; called by muse, mutect2
- CFAP54 | c.6289C>T p.Q2097* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV61570698; called by muse, mutect2
- CLTCL1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99595497; called by muse, mutect2
- COL5A1 | c.5348G>A p.R1783H | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs777045810, COSV65665436; ClinVar: uncertain significance; called by muse, mutect2
- COLEC11 | c.759C>A p.D253E | Missense Mutation (SNP) | VAF 54/674 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52594012; called by muse, mutect2
- CRABP1 | c.366G>A p.T122= | Splice Region (SNP) | VAF 12/209 reads (6%) | catalogued as rs201961718; called by muse, mutect2
- CTTN | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57233761; called by muse, mutect2
- DCC | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.281); catalogued as rs868720170; called by muse, mutect2
- DNAH5 | c.9634G>C p.E3212Q | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV99453602; called by muse, mutect2
- DNAH6 | c.11717A>G p.N3906S | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1197727474; called by muse, mutect2
- DYRK4 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50541884; called by muse, mutect2, varscan2
- FAN1 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV58728150; called by muse, mutect2, varscan2
- FAT2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753576697; called by muse, mutect2, varscan2
- FOXRED2 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 20/258 reads (8%) | catalogued as COSV99340623; called by muse, mutect2
- GAREM2 | c.2622C>G p.I874M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as rs540110481; called by mutect2, varscan2
- GPALPP1 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766454946; called by muse, mutect2
- HAO1 | c.1028C>G p.A343G | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV66492581; called by muse, mutect2
- HECTD4 | c.5170C>G p.Q1724E | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV66396551; called by muse, mutect2, varscan2
- HMGXB3 | c.4421A>G p.Y1474C (on ENST00000613459; = p.Y1228C on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/604 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992952342; called by muse, mutect2
- KCTD5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57064312; called by muse, mutect2, varscan2
- KDM2A | c.1155G>C p.L385F | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV67082195; called by muse, mutect2
- LAMB3 | c.3264G>C p.L1088F | Missense Mutation (SNP) | VAF 22/666 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs1258644211; called by muse, mutect2
- LAMC3 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs768726105; called by muse, mutect2
- LATS1 | c.1821G>T p.K607N | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV53590291; called by muse, mutect2
- MAP1S | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 58/804 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60724729; called by muse, mutect2
- MAPK15 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs782507603; called by muse, mutect2
- MEI1 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs185835285; called by muse, mutect2, varscan2
- MICAL3 | c.2740C>G p.Q914E | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as rs929964344; called by muse, mutect2
- MUC22 | c.4022C>T p.S1341L | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT tolerated (0.16); catalogued as rs1465574858; called by muse, mutect2
- MUTYH | c.1604C>G p.S535C | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV58344186; called by muse, mutect2
- MYEF2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV99981993; called by muse, mutect2
- MYO10 | c.5710G>A p.E1904K | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs773601311, COSV57025858; called by muse, mutect2
- NKTR | c.3472A>G p.I1158V | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755930710; called by muse, mutect2, varscan2
- NUP155 | c.3527C>G p.S1176C (on ENST00000231498 / NM_153485.3; = p.S1117C on NM_004298.4) | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV51527017; called by muse, mutect2
- OBSCN | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1434852395, COSV52755128; called by muse, mutect2
- OR2L5 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV62365471; called by muse, mutect2
- OR8B3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs1420062545; called by muse, varscan2
- OTOF | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255710513, COSV55495095; called by muse, mutect2, varscan2
- PCDHGA2 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 61/551 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV53955710; called by muse, mutect2, varscan2
- PCGF1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.598); catalogued as rs1033484434; called by muse, mutect2, varscan2
- PNPT1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 12/252 reads (5%) | catalogued as COSV53178787; called by muse, mutect2
- POLD1 | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs780926432; ClinVar: uncertain significance; called by muse, mutect2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- PPIL4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs749725290; called by muse, mutect2
- RGS12 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778464386; called by muse, mutect2, varscan2
- ROS1 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.703); catalogued as COSV63851582, COSV63862181; called by muse, mutect2
- RYR1 | c.5658G>C p.E1886D | Missense Mutation (SNP) | VAF 33/453 reads (7%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.525); catalogued as COSV62105429; called by muse, mutect2
- SALL4 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.374); catalogued as rs147195029; ClinVar: likely benign / benign; called by muse, mutect2
- SAMD9L | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV59084219; called by muse, mutect2, varscan2
- SHANK2 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 62/1374 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs782049538, COSV53625215; called by muse, mutect2
- SLK | c.3158A>G p.N1053S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs545873370; called by muse, mutect2
- SMAD4 | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61684595; called by muse, mutect2
- SNX7 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV60269946; called by muse, mutect2
- SPG11 | c.5974C>G p.R1992G | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as CM070960; called by muse, mutect2, varscan2
- STAG3 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372110074; called by muse, mutect2, varscan2
- TBX5 | c.1312C>G p.R438G | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV59862204; called by muse, mutect2
- TCF20 | c.1093A>T p.S365C | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1175393381; called by muse, mutect2, varscan2
- TCTN2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 39/674 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV57635322; called by muse, mutect2
- TLR8 | c.1773G>C p.L591F (on ENST00000218032 / NM_138636.5; = p.L609F on NM_016610.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54318464, COSV54319203; called by muse, mutect2, varscan2
- TMEM200C | c.1297C>A p.R433S | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.068); catalogued as COSV67309698; called by muse, mutect2
- TRPM4 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 45/500 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs564964090; called by muse, mutect2
- TTN | c.100084G>A p.D33362N (on ENST00000591111; = p.D25938N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/213 reads (4%) | PolyPhen probably damaging (0.998); catalogued as COSV100601252; called by muse, mutect2
- USP19 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV60049105; called by muse, mutect2, varscan2
- ZFP28 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 76/505 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.108); catalogued as rs1421459138, COSV100019312; called by muse, mutect2, varscan2
- ZMYM2 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | catalogued as COSV67034380, COSV67035832; called by muse, mutect2, varscan2
- ZNF302 | c.992G>C p.S331T (on ENST00000627982; = p.S252T on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV71063520; called by muse, mutect2, varscan2
- ZNF347 | c.1113A>C p.K371N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100498194; called by muse, mutect2
- ZNF514 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99727827; called by muse, mutect2, varscan2
- ZNF665 | c.1474C>T p.L492F (on ENST00000600412; = p.L557F on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776449782; called by muse, mutect2, varscan2
- A1BG | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- AC004997.1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- ACACA | c.4424C>G p.S1475C | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ADCY8 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- ADGRF5 | c.3646C>T p.Q1216* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- AHNAK | c.4747G>A p.D1583N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- APC2 | c.4559C>T p.A1520V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- APOL4 | c.721A>G p.K241E (on ENST00000352371 / NM_145660.2; = p.K238E on NM_030643.4) | Missense Mutation (SNP) | VAF 33/518 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2
- ARF6 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF6 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ARMCX5 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ASH1L | c.2406G>C p.K802N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ATRNL1 | c.299C>G p.T100R | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BAZ1A | c.4627G>A p.D1543N | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- BCAR1 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- BNC2 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.025); called by muse, mutect2
- BRPF1 | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC17 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.085); called by muse, mutect2
- CCRL2 | c.426G>C p.R142S | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDCA2 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CDH2 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- COL6A5 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CTNND1 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- CTNND1 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2
- DACT3 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2
- DCSTAMP | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIDO1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIPK1A | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2
- DISP3 | c.3782T>A p.L1261Q | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPN2 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2
- FBXW5 | c.1298C>G p.P433R | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2
- FSD1 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.028); called by muse, mutect2
- GABRG1 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2
- GPT | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GRIA3 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- GRK6 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- IGSF10 | c.3975C>A p.F1325L | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- IL25 | c.534G>C p.*178Yext*59 | Nonstop Mutation (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- KAZN | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2
- KCNH5 | c.1532C>G p.S511* | Nonsense Mutation (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- KCNJ3 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2
- KDF1 | c.496_511del p.L166Cfs*77 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- LAMA4 | c.2908G>A p.D970N (on ENST00000230538 / NM_001105206.3; = p.D963N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- LAYN | c.841C>G p.P281A (on ENST00000375615 / NM_001258390.1; = p.P273A on NM_178834.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2
- LHX8 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2
- LILRB1 | c.1975G>T p.A659S (on ENST00000427581; = p.A608S on NM_006669.6) | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.209); called by muse, varscan2
- LONRF1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MRTFB | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2
- MTO1 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MUC16 | c.38417T>A p.L12806Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MUC16 | c.6857C>G p.S2286* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.9816G>C p.E3272D | Missense Mutation (SNP) | VAF 60/584 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.067); called by mutect2, varscan2
- MYH7B | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); called by muse, mutect2
- NEBL | c.1648A>T p.R550W | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- NKX6-2 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NOL10 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOTCH1 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 52/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NR2C2 | c.1694G>C p.G565A (on ENST00000393102; = p.G584A on NM_003298.5) | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2
- NSF | c.2008A>T p.I670F | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- OR11H6 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2
- OR4A5 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- PCM1 | c.1601A>T p.E534V | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PCNT | c.4576G>T p.D1526Y | Missense Mutation (SNP) | VAF 17/594 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.425); called by muse, mutect2
- PDE4A | c.1102G>T p.E368* (on ENST00000380702 / NM_001111307.2; = p.E129* on NM_006202.3) | Nonsense Mutation (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- PDE6C | c.1563G>C p.L521F | Missense Mutation (SNP) | VAF 39/528 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGP | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 73/523 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIAS4 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHG5 | c.3052A>G p.R1018G (on ENST00000400915 / NM_001042663.3; = p.R981G on NM_020631.6) | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- POLA1 | c.2380C>T p.H794Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPM1H | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 31/337 reads (9%) | called by muse, mutect2
- PRICKLE1 | c.2160G>T p.E720D | Missense Mutation (SNP) | VAF 34/562 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.026); called by muse, mutect2
- PRR23A | c.698C>G p.P233R | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PSMC5 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- RAB3GAP1 | c.1344C>G p.F448L | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RB1CC1 | c.1643G>C p.R548T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RNF213 | c.10693C>A p.L3565M | Missense Mutation (SNP) | VAF 53/569 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- RNF7 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2
- RTN1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2
- SEC24D | c.2884G>A p.V962M | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2
- SH3TC2 | c.3101T>C p.F1034S | Missense Mutation (SNP) | VAF 30/626 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.135); called by muse, mutect2
- SIGLEC10 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- SLC12A9 | c.1235_1242del p.G412Efs*86 | Frame Shift Del (DEL) | VAF 88/704 reads (13%) | called by mutect2, pindel, varscan2
- SLC25A43 | c.281T>G p.V94G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, varscan2
- SP8 | c.377C>G p.S126C (on ENST00000361443 / NM_198956.4; = p.S144C on NM_182700.6) | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- STRC | c.4186C>G p.L1396V | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SUCLG2 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.617); called by muse, mutect2
- TFIP11 | c.859C>G p.H287D | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- TLR8 | c.1654G>A p.E552K (on ENST00000218032 / NM_138636.5; = p.E570K on NM_016610.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- TMEM132E | c.944T>A p.V315D (on ENST00000321639; = p.V405D on NM_001304438.2) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by muse, mutect2
- TMEM151A | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM39A | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TMEM67 | c.2557-1G>C p.X853_splice | Splice Site (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- TMTC1 | c.1322C>A p.T441N (on ENST00000539277 / NM_001193451.2; = p.T333N on NM_175861.3) | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.056); called by muse, mutect2
- TRIM24 | c.1311G>C p.Q437H | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TYW1B | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- UBE2R2 | c.386C>G p.S129* | Nonsense Mutation (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- USP26 | c.1599G>C p.K533N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2
- USP51 | c.2011C>G p.R671G | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VARS1 | c.1895C>G p.P632R | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, varscan2
- VNN2 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2
- WASHC2A | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 68/818 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ZC3H3 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF165 | c.1406C>G p.S469* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2
- ZNF214 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2
- ZNF236 | c.2006C>G p.S669C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF544 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.3986C>G p.S1329C | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- ZNF865 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT deleterious (0.01); called by muse, mutect2
- ZNF99 | c.774A>T p.K258N | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- ABHD17A | c.360T>C p.N120= (on ENST00000292577 / NM_001130111.2; = p.N171= on NM_031213.4) | Silent (SNP) | VAF 28/369 reads (8%) | catalogued as COSV51749141, COSV51750920; called by muse, mutect2
- ACCSL | c.1290C>T p.I430= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as rs780585393; called by muse, varscan2
- ATP10A | c.2460A>G p.K820= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV100791023; called by muse, mutect2
- C2 | c.609C>T p.I203= | Silent (SNP) | VAF 62/707 reads (9%) | catalogued as rs746577678; called by muse, mutect2
- CACNB4 | c.564A>T p.V188= | Silent (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- CALR | c.946C>T p.L316= | Silent (SNP) | VAF 48/534 reads (9%) | catalogued as rs779969842; called by muse, mutect2
- CDAN1 | c.1005G>T p.R335= | Silent (SNP) | VAF 20/676 reads (3%) | called by muse, mutect2
- CHST4 | c.291G>C p.L97= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- CMIP | c.225C>T p.I75= | Silent (SNP) | VAF 34/340 reads (10%) | called by muse, mutect2, varscan2
- COG2 | c.1249T>C p.L417= | Silent (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- CSAD | c.519G>A p.Q173= (on ENST00000444623 / NM_001244705.2; = p.Q200= on NM_015989.5) | Silent (SNP) | VAF 36/488 reads (7%) | called by muse, mutect2
- CUBN | c.8169A>G p.Q2723= | Silent (SNP) | VAF 39/528 reads (7%) | catalogued as rs762192732; called by muse, mutect2
- DST | c.4359A>G p.V1453= (on ENST00000361203 / NM_001374722.1; = p.V1127= on NM_015548.5) | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- DVL1 | c.1545G>C p.G515= (on ENST00000378888 / NM_001330311.2; = p.G490= on NM_004421.3) | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- EDEM3 | c.900G>A p.L300= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV58925787; called by muse, mutect2, varscan2
- EDRF1 | c.1311C>G p.L437= (on ENST00000356792 / NM_001202438.2; = p.L403= on NM_015608.2) | Silent (SNP) | VAF 36/434 reads (8%) | called by muse, mutect2
- FAT2 | c.8220C>T p.F2740= | Silent (SNP) | VAF 34/346 reads (10%) | called by muse, mutect2
- FGD6 | c.1353A>G p.V451= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as rs537543841; called by muse, mutect2
- FLYWCH1 | c.1332T>C p.A444= (on ENST00000253928 / NM_001308068.2; = p.A443= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/374 reads (17%) | catalogued as rs766622655; called by muse, mutect2, varscan2
- GANAB | c.798G>A p.L266= | Silent (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- JCAD | c.879C>A p.L293= | Silent (SNP) | VAF 29/290 reads (10%) | catalogued as COSV100948158; called by muse, mutect2, varscan2
- KRT6B | c.435G>A p.L145= | Silent (SNP) | VAF 62/1149 reads (5%) | called by muse, mutect2
- KRT83 | c.354C>G p.L118= | Silent (SNP) | VAF 73/867 reads (8%) | catalogued as COSV53339372; called by muse, mutect2
- LILRA4 | c.792C>T p.P264= | Silent (SNP) | VAF 32/382 reads (8%) | catalogued as rs1333156854; called by muse, mutect2
- LONP1 | c.1641C>T p.F547= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs757756532; called by muse, mutect2
- LRRC75A | c.579G>C p.V193= (on ENST00000470794 / NM_001113567.3; = p.D155H on NM_207387.4) | Silent (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- MANBA | c.753G>A p.V251= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- MROH8 | c.1494G>A p.K498= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- MYCBP2 | c.642C>T p.L214= (on ENST00000357337; = p.L252= on NM_015057.5) | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs773275265; called by muse, varscan2
- NAT10 | c.2913G>A p.E971= | Silent (SNP) | VAF 25/234 reads (11%) | catalogued as rs1170854461; called by muse, mutect2
- NHSL2 | c.1323C>G p.V441= (on ENST00000510661; = p.V807= on NM_001013627.2) | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as rs750294021; called by muse, mutect2, varscan2
- OR52I2 | c.69C>G p.V23= | Silent (SNP) | VAF 13/232 reads (6%) | called by muse, mutect2
- PDE6A | c.2016C>T p.A672= | Silent (SNP) | VAF 31/365 reads (8%) | called by muse, mutect2
- PEX2 | c.612G>A p.L204= | Silent (SNP) | VAF 16/163 reads (10%) | catalogued as rs758460841; called by muse, mutect2
- PIGT | c.543C>G p.V181= | Silent (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- PKD1 | c.2613G>A p.E871= | Silent (SNP) | VAF 78/430 reads (18%) | called by muse, mutect2, varscan2
- PLCD4 | c.1524C>T p.F508= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- PLEC | c.13428C>T p.G4476= (on ENST00000322810 / NM_201380.4; = p.G4366= on NM_000445.5) | Silent (SNP) | VAF 79/323 reads (24%) | called by muse, mutect2, varscan2
- PRDM6 | c.1557C>T p.H519= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs1305393659; called by muse, mutect2
- RAVER1 | c.465C>T p.F155= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs150272169, COSV50328228; called by muse, mutect2
- RFPL4A | c.573C>T p.C191= | Silent (SNP) | VAF 104/553 reads (19%) | catalogued as COSV101467269; called by muse, mutect2, varscan2
- RILPL1 | c.1095G>A p.K365= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- RPS5 | c.261C>G p.L87= | Silent (SNP) | VAF 38/547 reads (7%) | called by muse, mutect2
- RPS6KA5 | c.498A>G p.E166= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- SART1 | c.2001G>A p.S667= | Silent (SNP) | VAF 43/406 reads (11%) | catalogued as rs1258012898; called by muse, mutect2, varscan2
- SCN3A | c.3984T>C p.L1328= | Silent (SNP) | VAF 32/354 reads (9%) | catalogued as COSV99326817; called by muse, mutect2
- SLC9A2 | c.615C>A p.L205= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- SPARCL1 | c.24A>G p.L8= | Silent (SNP) | VAF 13/189 reads (7%) | catalogued as rs574601884; called by muse, mutect2
- SPEG | c.7020C>T p.S2340= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as rs1247201829; called by muse, mutect2
- STK36 | c.1518G>T p.L506= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV55326156; called by muse, mutect2, varscan2
- TBX18 | c.174C>T p.G58= | Silent (SNP) | VAF 41/510 reads (8%) | called by muse, mutect2
- TCF7 | c.1131T>C p.D377= (on ENST00000395029; = p.D262= on NM_201634.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/370 reads (9%) | catalogued as rs376624735; called by muse, mutect2
- TIMELESS | c.2085G>C p.L695= | Silent (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- TMEM131L | c.1347C>T p.G449= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
- TMEM164 | c.183G>A p.L61= | Silent (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- TMEM65 | c.66C>T p.A22= | Silent (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- TREML2 | c.255C>A p.A85= | Silent (SNP) | VAF 19/239 reads (8%) | called by muse, mutect2
- TRIP11 | c.5148G>A p.V1716= | Silent (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- VIT | c.1470C>T p.C490= (on ENST00000389975 / NM_001177969.1; = p.C505= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/335 reads (7%) | called by muse, mutect2
- ZBTB46 | c.615C>T p.A205= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as rs139982660; called by muse, mutect2, varscan2
- ZNF165 | c.777C>T p.L259= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV66103055; called by muse, mutect2, varscan2
- ZNF248 | c.1578G>C p.G526= | Silent (SNP) | VAF 24/287 reads (8%) | called by muse, mutect2
- ZXDB | c.1053C>G p.L351= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV66492782; called by muse, mutect2, varscan2
- ABHD3 | c.555+369C>T | Intron (SNP) | VAF 9/154 reads (6%) | catalogued as COSV100004399; called by muse, mutect2
- AC022415.2 | c.*2158A>G | 3'UTR (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- AC136604.1 | n.296C>G | RNA (SNP) | VAF 26/373 reads (7%) | called by muse, mutect2
- ANO1 | c.-36G>A | 5'UTR (SNP) | VAF 21/567 reads (4%) | called by muse, mutect2
- C8orf44-SGK3 | c.-121-25953C>G | Intron (SNP) | VAF 17/519 reads (3%) | called by muse, mutect2
- C8orf82 | c.-87G>C | 5'UTR (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- CUL4B | c.2493+11C>G | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- DDX11 | c.-4-166C>T | Intron (SNP) | VAF 24/326 reads (7%) | catalogued as rs1811284; called by muse, mutect2
- FAM157A | n.129C>G | RNA (SNP) | VAF 13/243 reads (5%) | called by muse, mutect2
- HDDC2 | c.-3C>T | 5'UTR (SNP) | VAF 26/282 reads (9%) | called by muse, mutect2
- HSPA9 | c.1183-692G>A | Intron (SNP) | VAF 3/33 reads (9%) | catalogued as rs1467822595; called by muse, mutect2
- HTR4 | c.*1637C>T | 3'UTR (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- ITGB3BP | c.6-1547C>T | Intron (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- LPP | c.1114-19443C>A | Intron (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- LRP6 | chr12:12115316 G>A | 3'Flank (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- MTSS1 | c.1404+123G>C | Intron (SNP) | VAF 31/600 reads (5%) | catalogued as COSV61496081; called by muse, mutect2
- MYO19 | c.894+752G>A | Intron (SNP) | VAF 20/257 reads (8%) | called by muse, mutect2
- NEIL1 | c.-23+376C>G | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- OFCC1 | n.1746G>C | RNA (SNP) | VAF 28/192 reads (15%) | called by muse, mutect2
- PABPC1P2 | n.947C>T | RNA (SNP) | VAF 28/296 reads (9%) | catalogued as rs1424629659; called by muse, mutect2
- PTPRO | c.2748-41G>C | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- RADIL | c.2291-108C>G | Intron (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2
- RHOJ | c.498+34T>C | Intron (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- SAMD13 | c.226-4627C>T | Intron (SNP) | VAF 17/230 reads (7%) | called by muse, mutect2
- SERPINB6 | c.48-26G>A | Intron (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- TCIRG1 | c.1166-493G>A | Intron (SNP) | VAF 17/380 reads (4%) | called by muse, mutect2
- TMEM135 | c.*6556C>T | 3'UTR (SNP) | VAF 42/555 reads (8%) | catalogued as rs968516715; called by muse, mutect2
- TRAPPC9 | c.2811-22129del | Intron (DEL) | VAF 135/599 reads (23%) | called by mutect2, pindel, varscan2
- TTYH1 | chr19:54415226 C>G | 5'Flank (SNP) | VAF 12/385 reads (3%) | called by muse, mutect2
- UGDH | c.-8+230C>G | Intron (SNP) | VAF 35/318 reads (11%) | catalogued as rs1490523112; called by muse, mutect2, varscan2
- ZNF638 | c.-68A>T | 5'UTR (SNP) | VAF 25/294 reads (9%) | called by muse, mutect2
